Gene-level copy-number profile of tumor specimen TCGA-OR-A5J4-01A from TCGA case TCGA-OR-A5J4, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 23.1 years (8,451 days).
Specimen TCGA-OR-A5J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.8aa24da8-071b-4cd2-a1d8-480ee049c863.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5J4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/25d7a639-db20-4b40-bb13-55146b016206

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,008; copy number 2: 26,937; copy number 3: 19,564; copy number 4: 5,790; copy number 5: 3,414; copy number 6: 950; copy number 7: 109; copy number 8: 16; copy number 9: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5J4-01A-11D-A29H-01): tumor purity 0.87, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,504 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:219,685,427–219,958,647, 1 gene, copy number 5 (within-gene range 2–5): SLC30A10.
- chr1:219,962,652–220,360,183, 17 genes, copy number 5: U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1.
- chr2:100,208,254–100,377,532, 4 genes, copy number 6: LINC01104, LONRF2, CYCSP7, AC012493.1.
- chr3:52,903,572–53,256,052, 8 genes, copy number 5: SFMBT1, AC096887.1, AC096887.2, SERBP1P3, RFT1, PRKCD, AC097015.1, TKT.
- chr3:53,290,640–53,290,751, 1 gene, copy number 5: Y_RNA.
- chr6:31,652,416–37,699,306, 286 genes, copy number 5 (broad region; genes not listed).
- chr6:38,168,451–38,640,148, 1 gene, copy number 5 (within-gene range 3–5): BTBD9.
- chr6:38,481,692–67,986,503, 440 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:67,933,485–67,934,682, 1 gene, copy number 5: AL713998.2.
- chr6:75,291,859–75,493,800, 1 gene, copy number 5 (within-gene range 3–5): FILIP1.
- chr6:75,357,214–93,419,559, 240 genes, copy number 5–7 (broad region; genes not listed).
- chr8:20,934,435–94,896,678, 1,215 genes, copy number 5–6 (broad region; genes not listed).
- chr9:89,005,771–94,726,575, 127 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr9:103,689,473–119,524,125, 231 genes, copy number 6–8 (broad region; genes not listed).
- chr9:132,944,000–138,203,325, 229 genes, copy number 5 (broad region; genes not listed).
- chr10:124,397,303–124,791,887, 11 genes, copy number 5: OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA.
- chr11:41,394,595–62,612,775, 627 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:62,466,817–64,222,296, 40 genes, copy number 6: MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P.
- chr12:64,920,845–64,982,524, 1 gene, copy number 6 (within-gene range 4–6): LINC02231.
- chr12:65,017,468–90,300,974, 345 genes, copy number 5–7 (broad region; genes not listed).
- chr12:90,617,759–90,622,822, 1 gene, copy number 6: AC084365.1.
- chr12:97,939,056–98,318,349, 4 genes, copy number 6: MIR4495, MIR4303, AC016152.1, AC008055.1.
- chr12:122,983,480–123,536,534, 22 genes, copy number 5 (within-gene range 2–5): PITPNM2, MIR4304, PITPNM2-AS1, AC026362.2, MPHOSPH9, AC073857.1, C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1, AC145423.1, AC145423.2, MIR3908.
- chr14:75,013,769–75,127,344, 5 genes, copy number 8 (within-gene range 3–8): MLH3, RNU6-689P, ACYP1, ZC2HC1C, NEK9.
- chr14:76,633,714–76,761,388, 4 genes, copy number 6 (within-gene range 3–6): CYCSP1, RPSAP3, AC007376.1, AC007376.2.
- chr16:11,196,177–11,527,245, 16 genes, copy number 5 (within-gene range 2–5): AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2.
- chr16:69,187,129–69,309,052, 1 gene, copy number 7 (within-gene range 3–7): SNTB2.
- chr16:69,240,549–69,704,666, 17 genes, copy number 7 (within-gene range 3–7): AC026474.1, AC026464.4, VPS4A, COG8, PDF, AC026464.6, AC026464.3, AC026464.1, NIP7, TMED6, TERF2, CYB5B, AC026464.5, AC026464.2, NFAT5, MIR1538, AC009032.1.
- chr19:29,606,283–30,060,797, 15 genes, copy number 9: POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4.
- chr20:24,445,391–37,530,543, 316 genes, copy number 5 (broad region; genes not listed).
- chr20:39,655,325–49,953,885, 253 genes, copy number 5 (broad region; genes not listed).
- chr22:24,269,346–24,774,720, 24 genes, copy number 5: AP000354.1, SPECC1L, SPECC1L-ADORA2A, ADORA2A, ADORA2A-AS1, UPB1, AP000355.1, GUCD1, SNRPD3, AP000356.5, LRRC75B, GGT1, AP000356.1, BCRP3, AP000356.4, AP000356.3, AP000356.2, POM121L10P, ARL5AP4, AP000357.1, AP000357.2, AP000358.1, CRIP1P4, PIWIL3.

Autosomal genes at a single copy (total copy number 1): 3,008. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
